CCDI case PBBXTG — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Heart, mediastinum, and pleura.
https://portal.gdc.cancer.gov/cases/6bd5f7ec-e568-4673-9aae-a04d100335eb

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Clear cell sarcoma, NOS: ICD-O-3 morphology code: 9044/3; Tissue or organ of origin: Heart; Age at diagnosis: 12.4 years (4,545 days).

Biospecimens (3 samples)
- Sample 0DK0AE: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DK0AI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DK0AS: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
